Gene-level copy-number profile of tumor specimen TCGA-TQ-A8XE-02A from TCGA case TCGA-TQ-A8XE, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 42.8 years (15,629 days).
Specimen TCGA-TQ-A8XE-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.423f20e8-5df2-4dd0-bdd7-bde9fce2ae9f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TQ-A8XE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ad079d7b-7f10-45f8-bf1e-2f9de88d199e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 542; copy number 1: 1,251; copy number 2: 2,295; copy number 3: 8,098; copy number 4: 45,044; copy number 5: 1,419; copy number 6: 605; copy number 7: 618; copy number 8: 263; copy number 9: 11; copy number 10: 59; copy number 11: 63; copy number 19: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TQ-A8XE-02A-11D-A40C-01): tumor purity 0.9, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr1:152,786,214–152,788,426, 1 gene: LCE1E.
- chr9:14,475–746,106, 19 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 76 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:44,712–254,637, 6 genes, copy number 11: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297.
- chr10:12,165,330–12,835,545, 11 genes, copy number 9 (within-gene range 7–9): NUDT5, CDC123, AL512770.1, RN7SL198P, CAMK1D, AL391314.1, RNU6ATAC39P, AL731559.1, MIR4480, MIR4481, MIR548Q.
- chr10:19,048,801–19,790,401, 1 gene, copy number 10 (within-gene range 7–10): MALRD1.
- chr10:19,489,101–20,552,046, 15 genes, copy number 10: HMGN1P20, AL354695.1, U3, RNA5SP303, AL157895.1, MTND1P37, MTND2P16, RNU6-1212P, AL353147.1, PLXDC2, AC069549.1, AC069549.2, AMD1P1, AL590032.1, MIR4675.
- chr10:20,804,293–20,841,560, 2 genes, copy number 10: MTND1P21, AL157398.1.
- chr10:23,694,746–24,547,848, 6 genes, copy number 10 (within-gene range 7–10): KIAA1217, NUP35P1, AC063961.1, MIR603, AL356113.1, AL353583.1.
- chr10:27,999,788–29,891,467, 35 genes, copy number 10: AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC, RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI, LINC01517, AL355376.1, RNU6-270P, LINC00837, AL355376.2, RNA5SP308, RPL21P93, LYZL1, AL158167.1, SVIL-AS1, PTCHD3P1, SVIL, MIR604, SNORD115, MIR938, CKS1BP2, RNU6-908P, AL353093.1.

Autosomal genes at a single copy (total copy number 1): 1,251. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
